Somatic mutation profile of tumor specimen ALCH-B2C6-TTP1-A (aliquot ALCH-B2C6-TTP1-A-1-0-D-A77J-36) from ALCHEMIST case ALCH-B2C6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 69.7 years (25,463 days).
Specimen ALCH-B2C6-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35a877d0-d33a-4404-b9da-2a52590e2d2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2C6-NB1-A (Blood Derived Normal), aliquot ALCH-B2C6-NB1-A-1-0-D-A77J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7bffc63a-4dea-4cab-b51e-31f1d935cd9d

The open-access MAF lists 227 somatic variants for this specimen: 165 protein-altering or splice-affecting, 31 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 131, Silent 31, Intron 20, Nonsense Mutation 14, Frame Shift Del 9, 5'UTR 4, Splice Site 4, Splice Region 3, RNA 3, Frame Shift Ins 2, 3'UTR 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYSF | c.3687C>A p.Y1229* | Nonsense Mutation (SNP) | VAF 20/255 reads (8%) | catalogued as rs375160101, CM090604; ClinVar: pathogenic; called by muse, mutect2
- AC053503.6 | c.821C>A p.A274E | Missense Mutation (SNP) | VAF 61/275 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780705791; called by muse, mutect2, varscan2
- AC136428.1 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV101434982, COSV101434991; called by muse, mutect2, varscan2
- AKT3 | c.1200G>A p.M400I | Missense Mutation (SNP) | VAF 20/295 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as rs1195814923; called by muse, mutect2
- AMBN | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 35/253 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV100534413; called by muse, mutect2, varscan2
- AOX1 | c.3715C>G p.P1239A | Missense Mutation (SNP) | VAF 58/553 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1286892570; called by muse, mutect2
- C5AR1 | c.610A>G p.I204V | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs755240188; called by muse, mutect2
- CHST2 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.444); catalogued as COSV58885151; called by muse, mutect2, varscan2
- CLBA1 | c.329C>G p.P110R | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.038); catalogued as rs998032106, COSV66348260; called by muse, mutect2, varscan2
- CNTLN | c.1538C>T p.S513L | Missense Mutation (SNP) | VAF 25/215 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99263051; called by muse, mutect2, varscan2
- COL19A1 | c.3419G>T p.G1140V | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); catalogued as rs1214842401, COSV59586178; called by muse, mutect2, varscan2
- COL2A1 | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 63/524 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs1359971369, COSV61531121; called by muse, mutect2, varscan2
- COL9A2 | c.1124G>C p.R375P | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.012); catalogued as rs370682522; called by muse, mutect2, varscan2
- DACT3 | c.314G>C p.G105A | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.37); catalogued as rs929161208; called by muse, mutect2
- DIS3 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 51/443 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs1250518714; called by muse, mutect2, varscan2
- EMD | c.640G>C p.G214R | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV63962592; called by muse, mutect2, varscan2
- EPB41L3 | c.1590G>C p.R530S | Missense Mutation (SNP) | VAF 24/241 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.214); catalogued as COSV59449912; called by muse, mutect2, varscan2
- FAM47C | c.2072G>T p.R691L | Missense Mutation (SNP) | VAF 56/364 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.147); catalogued as COSV63724565; called by muse, mutect2, varscan2
- GARNL3 | c.2491C>T p.R831* | Nonsense Mutation (SNP) | VAF 61/269 reads (23%) | catalogued as rs377506123; called by muse, mutect2, varscan2
- GPRASP1 | c.1352C>A p.A451D | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV64355020; called by muse, mutect2
- GPT | c.53C>A p.A18E | Missense Mutation (SNP) | VAF 36/314 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747432300; called by muse, mutect2, varscan2
- KRT6B | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 66/583 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV52886652; called by muse, mutect2, varscan2
- LRIG3 | c.721C>G p.L241V | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1232023500, COSV100292751; called by muse, mutect2
- LRP2BP | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.063); catalogued as rs753922441; called by mutect2, varscan2
- LTBR | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs950260552; called by muse, mutect2, varscan2
- MAP1LC3C | c.137G>C p.R46T | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.06); catalogued as COSV61804018; called by muse, mutect2, varscan2
- MAPKAPK3 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.684); catalogued as rs754225374, COSV63597041; called by muse, mutect2, varscan2
- MARCHF11 | c.964T>A p.L322I | Missense Mutation (SNP) | VAF 99/334 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.647); catalogued as rs750490048; called by muse, mutect2, varscan2
- MCM8 | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 40/232 reads (17%) | catalogued as COSV54521416; called by muse, varscan2
- MTHFR | c.1711C>T p.Q571* | Nonsense Mutation (SNP) | VAF 16/216 reads (7%) | catalogued as rs1434449406; called by muse, mutect2
- MTR | c.461C>G p.S154C | Missense Mutation (SNP) | VAF 54/425 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1311934439, COSV100855659, COSV100855808; called by muse, mutect2, varscan2
- NCK2 | c.1052C>G p.T351S | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as rs77614409; called by muse, mutect2
- NDN | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.229); catalogued as COSV59360140; called by muse, mutect2
- OR4C6 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.112); catalogued as COSV58603134, COSV58603870, COSV58604215; called by muse, mutect2
- OVCH1 | c.631A>G p.M211V | Missense Mutation (SNP) | VAF 25/278 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as rs781252383; called by muse, mutect2
- PIK3R2 | c.1011-1G>C p.X337_splice | Splice Site (SNP) | VAF 19/128 reads (15%) | catalogued as COSV55851089; called by muse, mutect2, varscan2
- PLCB4 | c.1316C>G p.S439* | Nonsense Mutation (SNP) | VAF 24/172 reads (14%) | catalogued as rs143544980; called by muse, mutect2, varscan2
- PTPN11 | c.1052G>T p.R351L | Missense Mutation (SNP) | VAF 99/428 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs397507534, COSV61012894; called by muse, mutect2, varscan2
- RASGEF1B | c.409C>G p.L137V | Missense Mutation (SNP) | VAF 43/428 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.014); catalogued as rs1241050542, COSV52336753; called by muse, mutect2, varscan2
- REG1A | c.201G>C p.M67I | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as COSV52071783; called by muse, mutect2, varscan2
- RSPH9 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 70/521 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1354678911; called by muse, mutect2, varscan2
- SCNN1A | c.1588G>C p.E530Q | Missense Mutation (SNP) | VAF 65/641 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.705); catalogued as rs780837673; called by muse, mutect2, varscan2
- SEPTIN12 | c.326C>T p.T109M | Missense Mutation (SNP) | VAF 36/270 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs762740565; called by muse, mutect2, varscan2
- SLCO4C1 | c.1169C>G p.S390* | Nonsense Mutation (SNP) | VAF 18/118 reads (15%) | catalogued as COSV60520980; called by muse, mutect2
- SPTA1 | c.575G>T p.R192L | Missense Mutation (SNP) | VAF 73/412 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV100935831, COSV63757423; called by muse, mutect2, varscan2
- TBX18 | c.1711C>G p.P571A | Missense Mutation (SNP) | VAF 26/207 reads (13%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.118); catalogued as rs752986259, COSV63736637; called by muse, mutect2, varscan2
- TDRD12 | c.1801G>A p.E601K | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.575); catalogued as rs892503341; called by muse, mutect2, varscan2
- TDRD9 | c.3169G>T p.V1057F | Missense Mutation (SNP) | VAF 52/440 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100175338, COSV59158223; called by muse, mutect2, varscan2
- TG | c.5747A>G p.Y1916C | Missense Mutation (SNP) | VAF 36/538 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs774352451, CM062012; called by muse, mutect2
- TMCO2 | c.381G>C p.E127D | Missense Mutation (SNP) | VAF 42/350 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV65646893; called by muse, mutect2, varscan2
- TMF1 | c.3079C>T p.Q1027* | Nonsense Mutation (SNP) | VAF 26/288 reads (9%) | catalogued as COSV68374786; called by muse, mutect2
- UBL3 | c.125A>G p.N42S | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as rs765268734; called by muse, mutect2, varscan2
- USP5 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as rs781856774; called by muse, mutect2, varscan2
- WASH6P | c.857C>G p.S286C | Missense Mutation (SNP) | VAF 70/542 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1288216642; called by muse, varscan2
- ZFP36L2 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.076); catalogued as rs780700434; called by muse, mutect2, varscan2
- AC011462.1 | c.724C>G p.P242A | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ACSS3 | c.76C>G p.P26A | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACTN4 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ALDH1A3 | c.91T>G p.F31V | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD33B | c.183C>G p.F61L | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOA5 | c.505G>C p.A169P | Missense Mutation (SNP) | VAF 176/303 reads (58%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- ASCC1 | c.719C>G p.S240C (on ENST00000342444 / NM_001369085.1; = p.S212C on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/332 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, varscan2
- ASXL3 | c.5530G>C p.E1844Q | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATP4A | c.2219A>G p.D740G | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- BCAM | c.1447C>G p.L483V | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BCL2L11 | c.596G>T p.*199Lext*70 (on ENST00000393256 / NM_138621.5; = p.*139Lext*70 on NM_006538.5) | Nonstop Mutation (SNP) | VAF 25/239 reads (10%) | called by muse, mutect2, varscan2
- BNC2 | c.2161G>T p.D721Y | Missense Mutation (SNP) | VAF 33/223 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- BPIFB6 | c.97+3G>A | Splice Region (SNP) | VAF 28/188 reads (15%) | called by muse, mutect2, varscan2
- C12orf4 | c.1550A>T p.Q517L | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C1QA | c.311del p.G104Afs*178 | Frame Shift Del (DEL) | VAF 38/271 reads (14%) | called by mutect2, pindel, varscan2
- CCSER1 | c.1194G>T p.E398D | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- CD4 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- CDC7 | c.1391G>C p.R464T | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.012); called by muse, mutect2
- CERS3 | c.1000-1G>C p.X334_splice | Splice Site (SNP) | VAF 15/106 reads (14%) | called by muse, mutect2, varscan2
- CFAP44 | c.997G>C p.D333H | Missense Mutation (SNP) | VAF 39/271 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CHD7 | c.6839G>C p.R2280T | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- CLDN3 | c.220C>G p.Q74E | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.3); called by muse, mutect2
- CNDP2 | c.969C>G p.F323L | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- COL24A1 | c.5128T>A p.S1710T | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- COLGALT1 | c.932T>C p.V311A | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COPA | c.545G>C p.R182T | Missense Mutation (SNP) | VAF 38/432 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2
- CRISPLD2 | c.1244C>G p.A415G | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- CSMD3 | c.7246+2T>C p.X2416_splice (on ENST00000297405 / NM_001363185.1; = p.X2312_splice on NM_052900.3) | Splice Site (SNP) | VAF 33/385 reads (9%) | called by muse, mutect2
- CSNK1D | c.362C>G p.S121* | Nonsense Mutation (SNP) | VAF 107/366 reads (29%) | called by muse, mutect2, varscan2
- CUBN | c.3474G>T p.W1158C | Missense Mutation (SNP) | VAF 43/515 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CUBN | c.3473G>T p.W1158L | Missense Mutation (SNP) | VAF 46/522 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CWH43 | c.792G>C p.W264C | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- DDX58 | c.707A>G p.N236S | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDX6 | c.586G>C p.V196L | Missense Mutation (SNP) | VAF 28/855 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2
- DHRS3 | c.631G>T p.G211* | Nonsense Mutation (SNP) | VAF 46/311 reads (15%) | called by muse, mutect2, varscan2
- DMBT1 | c.6266C>A p.S2089Y (on ENST00000338354 / NM_001377530.1; = p.S1332Y on NM_004406.3) | Missense Mutation (SNP) | VAF 31/302 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DMXL2 | c.7739C>T p.S2580L | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2
- DOCK7 | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 22/306 reads (7%) | called by muse, mutect2
- EBF2 | c.941T>G p.V314G | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ELF4 | c.397A>T p.N133Y | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); called by muse, mutect2
- EVC | c.1204C>G p.H402D | Missense Mutation (SNP) | VAF 43/357 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FAF1 | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 30/398 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2
- FAM124A | c.1382G>A p.R461K (on ENST00000322475 / NM_001242312.2; = p.R497K on NM_145019.4) | Missense Mutation (SNP) | VAF 17/193 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- FAM135B | c.1210A>C p.T404P | Missense Mutation (SNP) | VAF 29/256 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- FAM169A | c.1828C>A p.Q610K | Missense Mutation (SNP) | VAF 50/304 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- FLNC | c.1151G>A p.G384D | Missense Mutation (SNP) | VAF 36/286 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GADL1 | c.559_567del p.A187_N189del | In Frame Del (DEL) | VAF 32/318 reads (10%) | called by mutect2, pindel
- GATA3 | c.676G>C p.V226L | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GGCX | c.1324G>T p.D442Y | Missense Mutation (SNP) | VAF 65/486 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- INSRR | c.36C>A p.C12* | Nonsense Mutation (SNP) | VAF 36/306 reads (12%) | called by muse, mutect2, varscan2
- KANK4 | c.2229G>A p.E743= | Splice Region (SNP) | VAF 29/383 reads (8%) | called by muse, mutect2
- KCNT2 | c.2596-2A>G p.X866_splice | Splice Site (SNP) | VAF 24/145 reads (17%) | called by muse, mutect2, varscan2
- KHSRP | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.13); called by muse, mutect2
- KLHL17 | c.70C>G p.P24A | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.005); called by muse, mutect2
- MAGEB16 | c.331G>T p.D111Y | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- MAPK12 | c.739del p.A247Lfs*16 | Frame Shift Del (DEL) | VAF 16/158 reads (10%) | called by pindel, varscan2
- MAT2A | c.326C>G p.A109G | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, mutect2
- MBD5 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 32/334 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); called by muse, mutect2
- MED13L | c.2401del p.T801Qfs*10 | Frame Shift Del (DEL) | VAF 62/604 reads (10%) | called by mutect2, pindel, varscan2
- MIA3 | c.4669G>A p.E1557K | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MTOR | c.1493A>C p.Q498P | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.043); called by muse, mutect2
- MTUS1 | c.1087C>T p.Q363* | Nonsense Mutation (SNP) | VAF 20/128 reads (16%) | called by muse, varscan2
- MUC5AC | c.267C>G p.Y89* | Nonsense Mutation (SNP) | VAF 24/135 reads (18%) | called by muse, mutect2, varscan2
- MXRA8 | c.694C>A p.R232S | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYH15 | c.848A>T p.K283M | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO5C | c.4087dup p.M1363Nfs*19 | Frame Shift Ins (INS) | VAF 38/334 reads (11%) | called by mutect2, pindel, varscan2
- NBEAL2 | c.6156C>A p.S2052R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2
- NFRKB | c.3061G>T p.D1021Y (on ENST00000446488 / NM_001143835.2; = p.D1046Y on NM_006165.3) | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- NLRP1 | c.2725G>C p.D909H | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- NUDT8 | c.409G>C p.D137H | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2
- OOEP | c.88C>G p.P30A | Missense Mutation (SNP) | VAF 25/270 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.058); called by muse, mutect2
- OR2M7 | c.232G>C p.V78L | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.076); called by muse, mutect2
- OR2V2 | c.896dup p.M299Ifs*31 | Frame Shift Ins (INS) | VAF 14/88 reads (16%) | called by mutect2, pindel
- OR52L1 | c.167del p.A56Vfs*2 | Frame Shift Del (DEL) | VAF 61/517 reads (12%) | called by mutect2, pindel, varscan2
- OSBPL11 | c.949G>C p.D317H | Missense Mutation (SNP) | VAF 48/529 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.058); called by muse, mutect2
- PACC1 | c.119C>A p.P40Q | Missense Mutation (SNP) | VAF 37/278 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PAK6 | c.1537G>T p.A513S | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCDHB2 | c.1472C>G p.S491W | Missense Mutation (SNP) | VAF 50/462 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- PGLYRP2 | c.203A>G p.H68R | Missense Mutation (SNP) | VAF 14/195 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- PIWIL1 | c.1358C>G p.S453* | Nonsense Mutation (SNP) | VAF 33/343 reads (10%) | called by muse, mutect2, varscan2
- PLAUR | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- POGZ | c.1996A>G p.K666E | Missense Mutation (SNP) | VAF 50/423 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PPARGC1B | c.2428G>C p.E810Q | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.073); called by muse, varscan2
- PPP4R3C | c.1657C>A p.L553M | Missense Mutation (SNP) | VAF 39/285 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRPF40A | c.2745G>C p.K915N | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- PSMD6 | c.559T>C p.Y187H | Missense Mutation (SNP) | VAF 44/292 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.942); called by muse, varscan2
- PTGES3L-AARSD1 | c.835G>T p.A279S (on ENST00000421990 / NM_001136042.2; = p.A261S on NM_025267.3) | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.034); called by muse, varscan2
- RABGEF1 | c.1177G>C p.D393H (on ENST00000439720 / NM_001287061.2; = p.D380H on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/342 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, mutect2
- RBBP9 | c.76del p.W26Gfs*2 | Frame Shift Del (DEL) | VAF 38/360 reads (11%) | called by mutect2, varscan2
- RIMBP2 | c.1298del p.K433Rfs*20 | Frame Shift Del (DEL) | VAF 36/365 reads (10%) | called by mutect2, pindel, varscan2
- RIOX1 | c.1537G>C p.V513L | Missense Mutation (SNP) | VAF 25/300 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.066); called by muse, mutect2
- RNASEL | c.437A>G p.K146R | Missense Mutation (SNP) | VAF 59/528 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0); called by mutect2, varscan2
- SCN2A | c.721del p.L241* | Frame Shift Del (DEL) | VAF 120/565 reads (21%) | called by mutect2, pindel, varscan2
- SLITRK3 | c.1723C>G p.Q575E | Missense Mutation (SNP) | VAF 28/458 reads (6%) | SIFT tolerated (0.94); PolyPhen benign (0.001); called by muse, mutect2
- SNX17 | c.1381G>C p.A461P | Missense Mutation (SNP) | VAF 14/311 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2
- SPATA31A6 | c.1488G>T p.Q496H | Missense Mutation (SNP) | VAF 86/362 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- SPINK5 | c.2183_2187del p.V728Gfs*3 | Frame Shift Del (DEL) | VAF 58/512 reads (11%) | called by mutect2, pindel, varscan2
- SPTA1 | c.28G>T p.V10L | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- TMEM132B | c.52G>T p.V18L | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM132B | c.464A>T p.D155V | Missense Mutation (SNP) | VAF 37/339 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TNPO3 | c.2248G>A p.D750N | Missense Mutation (SNP) | VAF 18/337 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- TRAP1 | c.1312G>C p.A438P | Missense Mutation (SNP) | VAF 52/467 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- TSPAN19 | c.193T>C p.S65P | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- TYSND1 | c.429C>G p.F143L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- UBQLN2 | c.211_226del p.Q71Lfs*6 | Frame Shift Del (DEL) | VAF 54/502 reads (11%) | called by mutect2, pindel
- USP3 | c.868C>G p.Q290E | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDR62 | c.2521C>T p.L841= | Splice Region (SNP) | VAF 32/198 reads (16%) | called by muse, mutect2, varscan2
- ZC3H10 | c.937C>G p.H313D | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- ZNF285 | c.1075C>G p.L359V | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- ZNF525 | c.1192C>G p.L398V | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- ACSS3 | c.1686A>T p.A562= | Silent (SNP) | VAF 30/192 reads (16%) | called by muse, mutect2, varscan2
- AL592490.1 | c.2163C>G p.A721= | Silent (SNP) | VAF 16/140 reads (11%) | called by muse, mutect2, varscan2
- APOA5 | c.1092G>A p.G364= | Silent (SNP) | VAF 332/607 reads (55%) | catalogued as rs989362851; called by muse, mutect2, varscan2
- BIRC6 | c.5016T>A p.V1672= | Silent (SNP) | VAF 53/211 reads (25%) | called by muse, mutect2, varscan2
- CHST3 | c.795C>A p.R265= | Silent (SNP) | VAF 14/208 reads (7%) | called by muse, mutect2
- CNGB1 | c.3642G>T p.G1214= | Silent (SNP) | VAF 49/254 reads (19%) | catalogued as COSV99204255; called by muse, varscan2
- COL14A1 | c.4350C>G p.S1450= | Silent (SNP) | VAF 25/292 reads (9%) | called by muse, mutect2
- CREBBP | c.3552C>T p.V1184= | Silent (SNP) | VAF 55/514 reads (11%) | catalogued as COSV52114888; called by muse, mutect2, varscan2
- GABRQ | c.36C>A p.I12= | Silent (SNP) | VAF 15/123 reads (12%) | called by muse, mutect2, varscan2
- GPR162 | c.522G>A p.K174= | Silent (SNP) | VAF 48/370 reads (13%) | catalogued as COSV99163700; called by muse, mutect2, varscan2
- GPR162 | c.1155G>A p.V385= (on ENST00000311268 / NM_019858.2; = p.V101= on NM_014449.2) | Silent (SNP) | VAF 22/246 reads (9%) | called by muse, mutect2
- KLHL13 | c.1596A>C p.T532= | Silent (SNP) | VAF 48/332 reads (14%) | called by muse, varscan2
- LPA | c.3756C>G p.V1252= | Silent (SNP) | VAF 44/432 reads (10%) | called by muse, mutect2
- LRRC42 | c.132C>T p.F44= | Silent (SNP) | VAF 46/507 reads (9%) | called by muse, mutect2
- LTBR | c.291C>T p.I97= | Silent (SNP) | VAF 21/203 reads (10%) | called by muse, mutect2, varscan2
- LTBR | c.330C>G p.L110= | Silent (SNP) | VAF 22/138 reads (16%) | catalogued as rs376062437, COSV57439546; called by muse, mutect2, varscan2
- MUC17 | c.9729A>C p.S3243= | Silent (SNP) | VAF 31/138 reads (22%) | catalogued as rs1222712492; called by muse, mutect2, varscan2
- MXRA8 | c.693C>A p.R231= | Silent (SNP) | VAF 9/90 reads (10%) | called by muse, mutect2, varscan2
- OPRK1 | c.408C>T p.S136= | Silent (SNP) | VAF 42/418 reads (10%) | called by muse, mutect2
- OR5L2 | c.783G>A p.R261= | Silent (SNP) | VAF 66/335 reads (20%) | catalogued as COSV65723877; called by muse, varscan2
- PCDHB1 | c.96C>G p.R32= | Silent (SNP) | VAF 44/337 reads (13%) | called by muse, mutect2, varscan2
- PRRC2B | c.6078A>G p.P2026= | Silent (SNP) | VAF 28/261 reads (11%) | catalogued as rs1302654344; called by muse, mutect2, varscan2
- SAMD13 | c.292T>C p.L98= (on ENST00000370671; = p.L92= on NM_001010971.3) | Silent (SNP) | VAF 30/238 reads (13%) | catalogued as rs771822063; called by muse, mutect2, varscan2
- SCRN1 | c.856A>C p.R286= | Silent (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- SDC4 | c.81C>T p.I27= | Silent (SNP) | VAF 42/202 reads (21%) | catalogued as rs772766910; called by muse, mutect2, varscan2
- SKIDA1 | c.93A>G p.Q31= | Silent (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2, varscan2
- SNN | c.186G>C p.L62= | Silent (SNP) | VAF 14/179 reads (8%) | called by muse, mutect2
- SOX5 | c.1998A>G p.A666= | Silent (SNP) | VAF 18/119 reads (15%) | called by muse, mutect2, varscan2
- TMEM184C | c.804G>A p.L268= | Silent (SNP) | VAF 15/143 reads (10%) | catalogued as COSV56853508, COSV99669638; called by muse, mutect2, varscan2
- XKR3 | c.1162T>C p.L388= | Silent (SNP) | VAF 29/223 reads (13%) | called by muse, mutect2, varscan2
- ZFHX4 | c.3156T>C p.C1052= | Silent (SNP) | VAF 34/322 reads (11%) | called by muse, mutect2, varscan2
- AC093802.1 | n.1914+7061C>T | Intron (SNP) | VAF 22/209 reads (11%) | called by muse, mutect2, varscan2
- ADGRB3 | c.2481-749C>G | Intron (SNP) | VAF 22/216 reads (10%) | called by muse, mutect2
- AGAP7P | n.821G>C | RNA (SNP) | VAF 32/942 reads (3%) | called by muse, mutect2
- ARID4B | c.3448+930G>C | Intron (SNP) | VAF 37/285 reads (13%) | called by muse, mutect2, varscan2
- CARMIL2 | c.1591+9G>C | Intron (SNP) | VAF 15/89 reads (17%) | called by muse, mutect2, varscan2
- CCDC65 | chr12:48923954 C>A | 3'Flank (SNP) | VAF 44/328 reads (13%) | called by muse, mutect2, varscan2
- CTBP2 | c.58+11521G>C | Intron (SNP) | VAF 40/444 reads (9%) | catalogued as COSV58345184; called by muse, mutect2
- DENND5B | c.128-4561C>G | Intron (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2
- DST | c.1146-322G>C | Intron (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- DUSP3 | c.*17C>G | 3'UTR (SNP) | VAF 12/97 reads (12%) | called by muse, mutect2, varscan2
- EIF3F | c.*508G>T | 3'UTR (SNP) | VAF 23/197 reads (12%) | called by muse, mutect2, varscan2
- FUNDC2P2 | n.579G>T | RNA (SNP) | VAF 51/373 reads (14%) | catalogued as rs745487843; called by muse, mutect2, varscan2
- GFRA2 | c.41-107_41-106del | Intron (DEL) | VAF 14/90 reads (16%) | called by mutect2, pindel, varscan2
- HAND2-AS1 | n.512+1242C>G | Intron (SNP) | VAF 23/162 reads (14%) | called by muse, mutect2, varscan2
- HOXC4 | c.-124+16623C>T | Intron (SNP) | VAF 22/122 reads (18%) | called by muse, mutect2, varscan2
- HSD17B4 | c.1284+9A>C | Intron (SNP) | VAF 36/305 reads (12%) | called by muse, mutect2, varscan2
- JAML | c.772+392G>C | Intron (SNP) | VAF 86/1143 reads (8%) | called by muse, mutect2
- KIF23 | c.-59G>A | 5'UTR (SNP) | VAF 19/152 reads (13%) | catalogued as COSV52978535; called by muse, mutect2, varscan2
- LIMCH1 | c.936-7749C>G | Intron (SNP) | VAF 13/113 reads (12%) | catalogued as rs1172980786; called by muse, mutect2, varscan2
- LTBP4 | c.2759-19C>T | Intron (SNP) | VAF 22/251 reads (9%) | catalogued as rs778557315, COSV52579985; called by muse, mutect2
- MIR6511A3 | chr16:16372466 G>T | 3'Flank (SNP) | VAF 8/33 reads (24%) | called by mutect2, varscan2
- NAP1L6P | n.319G>C | RNA (SNP) | VAF 38/299 reads (13%) | called by muse, mutect2, varscan2
- OBSCN | c.11659+3565G>A | Intron (SNP) | VAF 30/252 reads (12%) | catalogued as COSV52844235, COSV99479861; called by muse, varscan2
- PRPF3 | c.-27G>C | 5'UTR (SNP) | VAF 24/296 reads (8%) | called by muse, mutect2
- PTBP3 | c.-34C>G | 5'UTR (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- QKI | c.1010-1197A>G | Intron (SNP) | VAF 21/159 reads (13%) | called by muse, mutect2, varscan2
- TTN | c.34265-5692A>C | Intron (SNP) | VAF 19/188 reads (10%) | called by muse, mutect2, varscan2
- UCKL1 | c.1022+32G>T | Intron (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- UQCRB | c.92-28T>C | Intron (SNP) | VAF 14/178 reads (8%) | called by muse, mutect2
- UROS | c.395-22A>G | Intron (SNP) | VAF 52/502 reads (10%) | called by muse, varscan2
- UTP14A | c.-9G>T | 5'UTR (SNP) | VAF 15/204 reads (7%) | called by muse, mutect2
